Surgical pathology report (de-identified scan), TCGA case TCGA-BK-A6W3, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-BK-A6W3-01A (Primary Tumor).

[page 1 of 2]
ICD-6-3

Adenocarcinoma, endometrioid
Site: Endometrium
8380/3
C54.1

gtD 7/25/13

Final Surgical Pathology Report

Procedure:

Diagnosis

Uterus and bilateral adnexa, resection:

Cervix: CIN-1, CIN2

Endometrium: Polypoid endometrioid type endometrial adenocarcinoma,
FIGO grade 2. Secretory type endometrium.

Myometrium: Probable very superficial myometrial invasion

Ovaries, left and right: No pathological diagnosis

Uterine tubes, left and right: No pathological diagnosis

Parametrium, left and right: No pathological diagnosis

Microscopic Description:

Histologic type: Endometrioid type endometrial adenocarcinoma
forming an exophytic polyp with adjacent secretory type
endometrium

Histologic grade: FIGO II. The tumor is greater than 5% but less
than 50% solid. There is micro-focal increased nuclear
grade (e.g. block A16).

Myometrial invasion: Focal probable very superficial myometrial
invasion (< 10%)

Vascular invasion: Absent

Endometrial hyperplasia: Absent

Lower uterine segment: Negative for malignancy

Uterine cervix: Transformation zone CIN 1 and CIN 2 are present.
CIN2 is present at the ectocervical epithelial edge of the
specimen in block RR2

Parametrium: Negative for malignancy

pTNM: T1a

MSI testing: Ordered on block A16

Other findings: None

Specimen

Uterus, cervix, bilateral tubes and ovaries

Clinical Information

Patient with grade 1 endometrial adenocarcinoma on biopsy
ASCUS Pap, for TAH BSO

Intraoperative Consultation

A. Uterus and bilateral adnexa, resection:

Polypoid endometrial adenocarcinoma.

Grade deferred to permanent sections.

No definite myometrial invasion seen.

Gross Description

The specimen is received unfixed labeled uterus, cervix, bilateral
tubes and ovaries and consists of a uterus and bilateral attached
adnexa weighing 142.8 g. The uterus measures 10.5 by 5.5 by 5 cm. The
ectocervix is white and measures 3 by 2.7 cm. The external os measures
1.4 x 0.1 cm. The left ovary is white and yellow with some purplish
cortical cysts. The specimen measures 2 point 2 x 2 by 1.2 cm. There is
adjacent pink uterine tube measuring 3 cm in length and 0.7 cm in
diameter. The right ovary is white with some cortical cysts. The ovary

[page 2 of 2]
measures 3.2 by 2.3 x 1.5 cm. There is some adjacent red soft tissue that might be 2 segments measure 2 and 1.5 cm in length and are up to 1 cm in diameter. The uterus is opened with a single incision at the 3:00 lateral side. There is a polypoid tumor and uterine cavity measuring 2.2 by 2.2 by 2.4 cm. Portions of polyp and underlying posterior myometrium are taken for frozen section diagnosis as requested (3 blocks). Additional sections after fixation.

Block summary: 1-3 left ovary, uterine tube and parametrium; 4-6 right ovary, uterine tube and parametrium; 7-11 anterior cervix and endomyometrium; 12-17 posterior cervix and endomyometrium. RR1-8 cervix

Crit. rla	hw 7/14/13	Yes	No
Hist/AA Discrepancy			✓

Source: NCI Genomic Data Commons file b3b087af-4319-4c68-bdc8-b87e8aeb5207 (TCGA-BK-A6W3.15A94B35-48FD-4F94-94E4-25F8084F8B91.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).